Surgical pathology report (de-identified scan), TCGA case TCGA-26-5136, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5136-01B (Primary Tumor).

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Tumor ()

A. Frozen Section Charge ()

B. Tumor #2 ()

CLINICAL HISTORY:

MRI revealed right occipital cerebellar lesion. She presents to OR for cleaning and resection.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

A. Tumor

B. Tumor #2

A. The specimen is received fresh, designated "tumor" and consists of a 0.5 x 0.3 x 0.3 cm portion of tan to beige soft tissue. A representative portion is submitted for frozen section. Frozen section diagnosis is "Malignant glioma," by . The frozen section tissue is submitted in cassette FSA1, and remaining tissue is submitted in cassette A2.

B. The specimen is received fresh, designated "tumor #2" and consists of a 1.8 x 1.2 x 0.8 cm aggregate of beige to gray-tan soft tissue pieces. A representative portion is submitted to the . Remaining tissue is submitted in cassette B1.

DIAGNOSIS:

A. "Tumor":

Glioblastoma multiforme (WHO Grade IV astrocytoma)

B. "Tumor #2":

Glioblastoma multiforme (WHO Grade IV astrocytoma)

COMMENT: reported these results to . "I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist:

Note: Test systems have been developed and their performance characteristics determined by . Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of as qualified to perform high complexity clinical laboratory testing.

Pathologist

Electronically signed

Source: NCI Genomic Data Commons file 677a08fd-3dfa-48c5-aae9-becfaad5148e (TCGA-26-5136.9B31DB65-32F7-49C1-BCC3-28455E2D3B6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).